Somatic mutation profile of tumor specimen HCM-CSHL-0586-C32-01A (aliquot HCM-CSHL-0586-C32-01A-01D-A881-36) from HCMI case HCM-CSHL-0586-C32, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0586-C32-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5380a4d4-2c72-48b3-89e7-a226d400652a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0586-C32-10A (Blood Derived Normal), aliquot HCM-CSHL-0586-C32-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de8f2629-8671-49cc-9084-b855b20f9d45

The open-access MAF lists 323 somatic variants for this specimen: 238 protein-altering or splice-affecting, 73 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 73, Nonsense Mutation 15, Intron 6, Splice Site 5, Frame Shift Del 4, 3'Flank 2, Splice Region 2, 3'UTR 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 107/257 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 280/546 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.4119+1G>C p.X1373_splice | Splice Site (SNP) | VAF 91/239 reads (38%) | catalogued as CS131684; called by muse, mutect2, varscan2
- ABI3BP | c.2709G>C p.Q903H | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs1378891053; called by muse, mutect2
- AFDN | c.4529G>C p.S1510T | Missense Mutation (SNP) | VAF 101/410 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.977); catalogued as COSV60053663; called by muse, mutect2, varscan2
- AK9 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs762842091; called by muse, mutect2, varscan2
- ALDOC | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 73/508 reads (14%) | catalogued as rs867498954, COSV52024219; called by muse, mutect2, varscan2
- AQR | c.2825C>G p.S942C | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778172785; called by muse, mutect2, varscan2
- ASAP2 | c.12G>C p.Q4H | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs928852938; called by muse, mutect2, varscan2
- ASPM | c.8379G>A p.M2793I | Missense Mutation (SNP) | VAF 132/476 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376057172; called by muse, mutect2, varscan2
- B3GNT2 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 96/350 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771301412, COSV100114040; called by muse, mutect2, varscan2
- CAPS2 | c.989G>C p.R330P | Missense Mutation (SNP) | VAF 83/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60823981; called by muse, mutect2, varscan2
- CCDC40 | c.1455C>G p.I485M | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.45); catalogued as COSV53897288; called by muse, mutect2, varscan2
- CERT1 | c.1876G>T p.V626L (on ENST00000405807 / NM_001130105.1; = p.V498L on NM_005713.3) | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs779820104, COSV54658074; called by muse, mutect2, varscan2
- CES1 | c.1108G>A p.E370K (on ENST00000361503 / NM_001025194.2; = p.E369K on NM_001266.5) | Missense Mutation (SNP) | VAF 95/581 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); catalogued as rs185780477, COSV100828576; called by muse, mutect2, varscan2
- CHPF | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 185/687 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV60533299; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 95/481 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CLSTN2 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.976); catalogued as rs1279936593; called by muse, mutect2, varscan2
- CLSTN2 | c.2710G>C p.E904Q | Missense Mutation (SNP) | VAF 90/461 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV71719844; called by muse, mutect2, varscan2
- COL24A1 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976118816; called by muse, mutect2, varscan2
- COL25A1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 156/644 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV67651309; called by muse, mutect2, varscan2
- CPLANE1 | c.134G>C p.R45T (on ENST00000425232; = p.R117T on NM_023073.3) | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as rs1324311439; called by muse, mutect2, varscan2
- CRACD | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 153/628 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as rs568276295, COSV51715441; called by muse, mutect2, varscan2
- EPS8L1 | c.1901C>G p.S634W (on ENST00000201647 / NM_133180.3; = p.S507W on NM_017729.3) | Missense Mutation (SNP) | VAF 224/828 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777409786; called by muse, mutect2, varscan2
- FAT4 | c.10367C>G p.S3456C | Missense Mutation (SNP) | VAF 130/456 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58696413; called by muse, mutect2, varscan2
- FBXL13 | c.1530G>C p.L510F | Missense Mutation (SNP) | VAF 64/260 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756557162; called by muse, mutect2, varscan2
- FCAR | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 239/697 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.296); catalogued as rs372465584, COSV62030495; called by muse, mutect2, varscan2
- FMN2 | c.3097C>G p.P1033A | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV60434495; called by muse, varscan2
- GMEB2 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 217/677 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as rs752805008, COSV56607678; called by muse, mutect2, varscan2
- GNE | c.1352G>A p.R451Q (on ENST00000396594 / NM_001128227.3; = p.R420Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs780092539, COSV64951478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN3A | c.1637C>A p.P546H | Missense Mutation (SNP) | VAF 50/486 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs758777062; called by mutect2, varscan2
- H2AZ2 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 195/631 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.397); catalogued as COSV56062069; called by muse, mutect2, varscan2
- H2BW2 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 157/294 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs373863467; called by muse, mutect2, varscan2
- H4C11 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs758581420, COSV100747976; called by muse, mutect2, varscan2
- HEATR5A | c.5491G>A p.E1831K | Missense Mutation (SNP) | VAF 136/263 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as COSV101119736; called by muse, mutect2, varscan2
- HFM1 | c.1969C>G p.R657G | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443376631; called by muse, mutect2, varscan2
- JADE2 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 93/434 reads (21%) | catalogued as COSV50927131; called by muse, mutect2, varscan2
- KCNC3 | c.1874G>C p.R625T | Missense Mutation (SNP) | VAF 276/825 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs913429586, COSV65387207; called by muse, mutect2, varscan2
- KCNQ4 | c.2035G>A p.V679I | Missense Mutation (SNP) | VAF 177/633 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV61275555; called by muse, mutect2, varscan2
- KCTD16 | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 99/509 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72579285; called by muse, mutect2, varscan2
- KIF13B | c.4674del p.S1559Afs*3 | Frame Shift Del (DEL) | VAF 177/845 reads (21%) | catalogued as rs1182415107; called by mutect2, pindel, varscan2
- L3MBTL2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 172/547 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs745928119; called by muse, mutect2, varscan2
- LETM1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 149/472 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs763003148; called by muse, mutect2, varscan2
- LRP2 | c.10070C>T p.S3357F | Missense Mutation (SNP) | VAF 92/462 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55574533; called by muse, mutect2, varscan2
- LY75-CD302 | c.5515G>C p.D1839H | Missense Mutation (SNP) | VAF 88/338 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs747473972; called by muse, varscan2
- MAFF | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 137/437 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV58299548; called by muse, mutect2, varscan2
- MAGEL2 | c.3235G>C p.E1079Q | Missense Mutation (SNP) | VAF 115/415 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV58566195; called by muse, mutect2, varscan2
- MASP1 | c.963C>G p.F321L | Missense Mutation (SNP) | VAF 78/447 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.198); catalogued as COSV51460744, COSV99397544; called by muse, mutect2, varscan2
- MEX3B | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 202/576 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.435); catalogued as rs538400491, COSV100313919; called by muse, mutect2, varscan2
- MORC1 | c.1596C>G p.I532M | Missense Mutation (SNP) | VAF 98/430 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV51730272; called by muse, mutect2, varscan2
- MROH2B | c.4675C>G p.P1559A | Missense Mutation (SNP) | VAF 45/331 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV68182763; called by muse, mutect2, varscan2
- MYNN | c.1160A>G p.Y387C | Missense Mutation (SNP) | VAF 94/431 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747581519; called by muse, mutect2, varscan2
- MYO6 | c.1737C>G p.I579M | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs763342831; called by muse, mutect2, varscan2
- NAA25 | c.823C>T p.R275* | Nonsense Mutation (SNP) | VAF 68/290 reads (23%) | catalogued as rs1287477535, COSV55709487; called by muse, mutect2, varscan2
- NOTCH3 | c.404C>A p.S135* | Nonsense Mutation (SNP) | VAF 212/786 reads (27%) | catalogued as rs1356781250; called by muse, mutect2, varscan2
- NPR3 | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 149/888 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV54092987; called by muse, mutect2, varscan2
- NRTN | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 283/557 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.094); catalogued as rs1292681887; called by muse, mutect2, varscan2
- OBSCN | c.12116G>C p.G4039A | Missense Mutation (SNP) | VAF 83/499 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV52735651; called by muse, mutect2, varscan2
- OR4S2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 57/526 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV56748245; called by muse, mutect2, varscan2
- OXR1 | c.327G>C p.L109F (on ENST00000442977 / NM_001198532.1; = p.L108F on NM_018002.3) | Missense Mutation (SNP) | VAF 79/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56326708; called by muse, mutect2, varscan2
- PALLD | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 119/451 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.05); catalogued as rs772476893, COSV54984881; called by muse, mutect2, varscan2
- PAPSS2 | c.1200G>C p.M400I | Missense Mutation (SNP) | VAF 72/290 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100753730; called by muse, mutect2, varscan2
- PARP12 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 127/459 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54934039; called by muse, mutect2, varscan2
- PCDH7 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 183/708 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337676; called by muse, mutect2, varscan2
- PGAP4 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 140/526 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66387982; called by muse, mutect2, varscan2
- PGPEP1L | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 104/604 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs766570886; called by muse, mutect2, varscan2
- PHKB | c.2791G>A p.D931N | Missense Mutation (SNP) | VAF 77/321 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs373243537, COSV54524124; called by muse, mutect2, varscan2
- PLCH1 | c.3826G>T p.E1276* (on ENST00000340059 / NM_001130960.2; = p.E1268* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 111/544 reads (20%) | catalogued as COSV58207497; called by muse, mutect2, varscan2
- PLEKHH1 | c.3323G>A p.R1108Q | Missense Mutation (SNP) | VAF 227/408 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1006856087; called by muse, mutect2, varscan2
- PLEKHO2 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 105/563 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60261708; called by muse, mutect2, varscan2
- PPP1R37 | c.46G>T p.G16C | Missense Mutation (SNP) | VAF 240/696 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.224); catalogued as rs1489093950; called by muse, mutect2
- PPP1R7 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 62/267 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs1299392369, COSV52145717; called by muse, mutect2, varscan2
- PRDM7 | c.50G>C p.R17T | Missense Mutation (SNP) | VAF 99/357 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); catalogued as COSV104434984; called by muse, mutect2, varscan2
- PTMA | c.190G>C p.E64Q (on ENST00000341369 / NM_001099285.2; = p.E63Q on NM_002823.5) | Missense Mutation (SNP) | VAF 67/302 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV58187895; called by muse, mutect2, varscan2
- RBL1 | c.769G>T p.D257Y | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.635); catalogued as COSV60331503; called by muse, mutect2, varscan2
- RDX | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV58193025; called by muse, mutect2, varscan2
- REM1 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 212/708 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.866); catalogued as COSV52427894; called by muse, mutect2, varscan2
- RNF167 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 244/762 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99337254; called by muse, mutect2, varscan2
- RPL8 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 140/780 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs778652220, COSV52799438; called by muse, mutect2, varscan2
- RUSC1 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 105/556 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV52741346; called by muse, mutect2, varscan2
- SBNO2 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 224/468 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as rs771453105; called by muse, mutect2, varscan2
- SBNO2 | c.1353C>G p.F451L | Missense Mutation (SNP) | VAF 184/375 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62323482; called by muse, mutect2, varscan2
- SCAI | c.706G>C p.E236Q (on ENST00000336505 / NM_001144877.3; = p.E259Q on NM_173690.5) | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); catalogued as COSV100332774; called by muse, mutect2, varscan2
- SGO1 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs201455258; called by muse, mutect2
- SHISA6 | c.1141G>A p.E381K (on ENST00000409168 / NM_001173461.1; = p.E432K on NM_207386.4) | Missense Mutation (SNP) | VAF 163/629 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as rs1413780172; called by muse, mutect2, varscan2
- SLC35G2 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101262014; called by muse, mutect2, varscan2
- SLC44A5 | c.1480G>C p.D494H | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV63769674; called by muse, mutect2, varscan2
- SLC9A3R1 | c.444C>T p.R148= | Splice Region (SNP) | VAF 63/828 reads (8%) | catalogued as rs146791449, COSV99379862; called by muse, mutect2
- SMG1 | c.9629A>G p.N3210S | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1403195291; called by muse, mutect2, varscan2
- STARD9 | c.7011G>C p.L2337F | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.535); catalogued as rs1279058394; called by muse, mutect2, varscan2
- SYMPK | c.2704G>C p.E902Q | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as COSV99842234; called by muse, mutect2, varscan2
- TUBD1 | c.223C>G p.Q75E | Missense Mutation (SNP) | VAF 180/436 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs774443751; called by muse, mutect2, varscan2
- USF3 | c.1984C>G p.Q662E | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs763985151, COSV57076619; called by muse, mutect2, varscan2
- WDR33 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 88/291 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs770304067, COSV100460372; called by muse, mutect2, varscan2
- ZBTB45 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 102/445 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs778329030, COSV54021032; called by muse, mutect2, varscan2
- ZNF652 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100755635; called by muse, mutect2, varscan2
- ZNF697 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 165/613 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101360129; called by muse, mutect2, varscan2
- ABCG8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 84/286 reads (29%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.01); called by muse, mutect2
- ACAN | c.71-1G>C p.X24_splice | Splice Site (SNP) | VAF 93/310 reads (30%) | called by muse, mutect2, varscan2
- ACSL6 | c.1336C>T p.L446F (on ENST00000379240; = p.L471F on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.309); called by muse, varscan2
- ADAMTS6 | c.420A>C p.Q140H | Missense Mutation (SNP) | VAF 76/350 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.38); called by muse, mutect2
- AJUBA | c.576_589del p.A193Rfs*108 | Frame Shift Del (DEL) | VAF 460/828 reads (56%) | called by mutect2, pindel, varscan2
- AKAP6 | c.5649C>G p.F1883L | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2
- AMBRA1 | c.1106C>T p.S369F (on ENST00000458649 / NM_001367468.1; = p.S279F on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 127/482 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AMOTL2 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 22/718 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.697G>C p.E233Q | Missense Mutation (SNP) | VAF 151/427 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ANKRD17 | c.1188T>A p.H396Q | Missense Mutation (SNP) | VAF 80/377 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANXA11 | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 99/526 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ARFGEF1 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 31/266 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ARHGEF9 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 111/189 reads (59%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.790C>A p.H264N | Missense Mutation (SNP) | VAF 68/155 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ATP5PD | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 100/1128 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.011); called by muse, mutect2
- BFAR | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 75/326 reads (23%) | called by muse, mutect2, varscan2
- BTBD7 | c.2323C>G p.Q775E | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BUB1 | c.2857A>G p.M953V | Missense Mutation (SNP) | VAF 125/412 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- BUB1 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 138/439 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C16orf91 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 228/864 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- C8orf48 | c.805A>T p.S269C | Missense Mutation (SNP) | VAF 87/390 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CAPRIN2 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 119/424 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CATSPERE | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 90/330 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CBFA2T2 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CDC42BPG | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 98/753 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFHR2 | c.179T>G p.V60G | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CLIC3 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 194/627 reads (31%) | called by muse, mutect2, varscan2
- CLUL1 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 125/791 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CNOT1 | c.4552G>A p.E1518K | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CUX1 | c.4097_4134del p.V1366Gfs*172 | Frame Shift Del (DEL) | VAF 110/614 reads (18%) | called by mutect2, pindel, varscan2
- CYC1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 122/591 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CYP2R1 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 152/417 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DAPK1 | c.857G>C p.R286T | Missense Mutation (SNP) | VAF 89/333 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DDAH1 | c.609G>C p.Q203H | Missense Mutation (SNP) | VAF 75/291 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DDIT3 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 147/572 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DGKK | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 202/356 reads (57%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DHCR24 | c.949G>C p.E317Q | Missense Mutation (SNP) | VAF 107/405 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMD | c.9391G>C p.D3131H | Missense Mutation (SNP) | VAF 132/250 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- DNAH7 | c.5101G>C p.E1701Q | Missense Mutation (SNP) | VAF 136/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSTYK | c.335C>T p.P112L | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DTL | c.1445G>T p.R482I | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- EEA1 | c.406G>C p.E136Q | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- EMILIN2 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 100/609 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ETNPPL | c.1068G>C p.L356F | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- FER | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GATA5 | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 385/1131 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GATA5 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 304/892 reads (34%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.703); called by muse, mutect2
- GFRA2 | c.891T>G p.Y297* | Nonsense Mutation (SNP) | VAF 20/422 reads (5%) | called by muse, mutect2
- GLG1 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GNPAT | c.1523-1G>A p.X508_splice | Splice Site (SNP) | VAF 29/153 reads (19%) | called by muse, mutect2, varscan2
- GRIA1 | c.2064G>A p.M688I | Missense Mutation (SNP) | VAF 71/337 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GRIN3A | c.1636C>A p.P546T | Missense Mutation (SNP) | VAF 48/484 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.44); called by mutect2, varscan2
- GSDMA | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 108/456 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HDAC4 | c.1776+1G>T p.X592_splice | Splice Site (SNP) | VAF 143/488 reads (29%) | called by muse, mutect2, varscan2
- HDAC4 | c.1776G>A p.Q592= | Splice Region (SNP) | VAF 144/493 reads (29%) | called by muse, mutect2, varscan2
- HECW2 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 125/442 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HERPUD1 | c.925C>G p.P309A | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HHAT | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HLA-A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 182/649 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- HS3ST1 | c.775G>C p.D259H | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- ID3 | c.269G>C p.G90A | Missense Mutation (SNP) | VAF 142/500 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-27 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- INTS6L | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 170/322 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQGAP3 | c.4184G>C p.R1395T | Missense Mutation (SNP) | VAF 31/187 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JAK2 | c.1835A>G p.N612S | Missense Mutation (SNP) | VAF 417/714 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KIAA1210 | c.2684C>T p.S895L | Missense Mutation (SNP) | VAF 143/283 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- KIF26B | c.3445G>T p.E1149* | Nonsense Mutation (SNP) | VAF 148/553 reads (27%) | called by muse, mutect2, varscan2
- KLHL10 | c.637C>G p.H213D | Missense Mutation (SNP) | VAF 35/286 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KLHL25 | c.1422C>G p.I474M | Missense Mutation (SNP) | VAF 119/545 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- LMTK2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 119/385 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC8A | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 148/496 reads (30%) | called by muse, mutect2, varscan2
- MED1 | c.4468C>T p.P1490S | Missense Mutation (SNP) | VAF 57/504 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MEF2D | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 57/305 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MTERF1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 116/366 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MTO1 | c.1432G>A p.D478N (on ENST00000370300 / NM_133645.3; = p.D453N on NM_012123.4) | Missense Mutation (SNP) | VAF 102/414 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NBR1 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 74/517 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NCBP2AS2 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 114/869 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- NDUFB3 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 89/307 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NFIL3 | c.162G>C p.K54N | Missense Mutation (SNP) | VAF 154/524 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- NFKB2 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 187/700 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NFKBIZ | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 90/465 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- NOTCH1 | c.6001C>G p.L2001V | Missense Mutation (SNP) | VAF 229/770 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP88 | c.1058G>C p.W353S | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NWD1 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.055); called by muse, mutect2
- OR14A2 | c.737_748delinsCACTGTT p.F246Sfs*12 | Frame Shift Del (DEL) | VAF 41/362 reads (11%) | called by pindel, varscan2*
- OR7G2 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 110/237 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- PARM1 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 143/512 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- PDE3B | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 207/546 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PIEZO2 | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 99/482 reads (21%) | SIFT tolerated (0.64); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PIK3CB | c.1909C>G p.Q637E | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- PKD1L1 | c.6822G>A p.M2274I | Missense Mutation (SNP) | VAF 154/594 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCE1 | c.4355A>G p.H1452R | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLEKHH1 | c.1041C>G p.N347K | Missense Mutation (SNP) | VAF 18/614 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- PPP1CA | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 189/897 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R4 | c.2533A>G p.T845A | Missense Mutation (SNP) | VAF 238/458 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRRT1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 129/516 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, varscan2
- PRUNE2 | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 123/470 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PZP | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RFX7 | c.2904G>A p.M968I (on ENST00000559447 / NM_001368074.1; = p.M1065I on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/399 reads (28%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RNF168 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 101/428 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- RPLP0 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 125/556 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SBNO2 | c.1152C>G p.I384M | Missense Mutation (SNP) | VAF 147/350 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SBNO2 | c.918C>G p.F306L | Missense Mutation (SNP) | VAF 212/405 reads (52%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SERPINB9 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 74/368 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SGIP1 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 160/597 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC12A5 | c.2338C>G p.L780V (on ENST00000454036 / NM_001134771.2; = p.L757V on NM_020708.5) | Missense Mutation (SNP) | VAF 169/564 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC16A5 | c.1218C>G p.I406M | Missense Mutation (SNP) | VAF 77/1349 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); called by muse, mutect2
- SLC4A10 | c.1618-1G>A p.X540_splice (on ENST00000446997 / NM_001354461.2; = p.X510_splice on NM_022058.4 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 81/269 reads (30%) | called by muse, mutect2, varscan2
- SLC6A18 | c.1639G>A p.A547T | Missense Mutation (SNP) | VAF 226/447 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- SLC8A3 | c.2132C>A p.A711E (on ENST00000381269 / NM_183002.3; = p.A709E on NM_033262.4) | Missense Mutation (SNP) | VAF 22/328 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- SLC9A3R1 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 146/1384 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SOX3 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 185/301 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SPIRE2 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 135/449 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- SRFBP1 | c.980G>A p.R327K | Missense Mutation (SNP) | VAF 137/419 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ST13 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 109/336 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STAT3 | c.232C>T p.L78F | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TADA2A | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 109/337 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- TARBP1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 208/607 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- TDRD5 | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 90/410 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TIGD7 | c.1584G>C p.L528F | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM88 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 212/652 reads (33%) | called by muse, mutect2, varscan2
- TOPBP1 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRAPPC9 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 123/478 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TTN | c.54344G>C p.R18115T (on ENST00000591111; = p.R10691T on NM_003319.4) | Missense Mutation (SNP) | VAF 101/421 reads (24%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ULK4 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 86/300 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USP49 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 50/504 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VANGL2 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 53/268 reads (20%) | called by muse, mutect2, varscan2
- VEPH1 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 91/466 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDCP | c.1729G>T p.E577* | Nonsense Mutation (SNP) | VAF 96/462 reads (21%) | called by muse, mutect2, varscan2
- WDFY3 | c.6620T>C p.L2207P | Missense Mutation (SNP) | VAF 66/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- WRNIP1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 167/798 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- ZBED9 | c.3717T>G p.S1239R | Missense Mutation (SNP) | VAF 106/452 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZC3H11B | c.2171G>C p.R724T | Missense Mutation (SNP) | VAF 108/843 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZCCHC2 | c.707C>G p.S236* | Nonsense Mutation (SNP) | VAF 317/656 reads (48%) | called by muse, mutect2, varscan2
- ZMYM4 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZMYM5 | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF462 | c.650A>C p.K217T | Missense Mutation (SNP) | VAF 198/592 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- ZNF622 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 48/811 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2
- ZNF623 | c.152T>G p.V51G | Missense Mutation (SNP) | VAF 25/971 reads (3%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2
- ZNF750 | c.842_843insTC p.H283Dfs*84 | Frame Shift Ins (INS) | VAF 128/378 reads (34%) | called by mutect2, pindel, varscan2
- ZNF761 | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 79/280 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ABCB4 | c.1095T>C p.Y365= | Silent (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- ADAP1 | c.981C>T p.I327= | Silent (SNP) | VAF 210/810 reads (26%) | catalogued as rs371003070; called by muse, mutect2, varscan2
- ADGRG1 | c.1704G>A p.L568= | Silent (SNP) | VAF 156/509 reads (31%) | catalogued as COSV101113398; called by muse, mutect2, varscan2
- ADORA1 | c.264C>G p.L88= | Silent (SNP) | VAF 96/462 reads (21%) | called by muse, mutect2, varscan2
- ANO10 | c.753C>T p.L251= | Silent (SNP) | VAF 103/422 reads (24%) | catalogued as rs753407149; called by muse, mutect2, varscan2
- ATXN2L | c.288C>T p.I96= | Silent (SNP) | VAF 165/569 reads (29%) | called by muse, mutect2, varscan2
- BRCA2 | c.2565A>C p.T855= | Silent (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- C1QL1 | c.408C>G p.L136= | Silent (SNP) | VAF 67/544 reads (12%) | called by muse, mutect2, varscan2
- CCDC180 | c.3906C>T p.F1302= | Silent (SNP) | VAF 116/408 reads (28%) | called by muse, mutect2, varscan2
- CCNB3 | c.3837G>A p.L1279= | Silent (SNP) | VAF 116/210 reads (55%) | called by muse, mutect2, varscan2
- CDHR4 | c.1317C>T p.N439= | Silent (SNP) | VAF 110/399 reads (28%) | catalogued as rs113873087, COSV58525768; called by muse, mutect2, varscan2
- CEP72 | c.1404G>A p.A468= | Silent (SNP) | VAF 107/632 reads (17%) | catalogued as rs953228337; called by muse, mutect2, varscan2
- CFL1 | c.483G>A p.L161= | Silent (SNP) | VAF 34/658 reads (5%) | called by muse, mutect2
- CNTROB | c.2676G>A p.P892= | Silent (SNP) | VAF 126/468 reads (27%) | catalogued as rs572722264, COSV100972613, COSV66609146; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2931C>T p.L977= | Silent (SNP) | VAF 221/579 reads (38%) | called by muse, mutect2, varscan2
- CRYGS | c.453C>G p.L151= | Silent (SNP) | VAF 108/552 reads (20%) | called by muse, mutect2, varscan2
- CUL9 | c.4512C>G p.L1504= | Silent (SNP) | VAF 108/456 reads (24%) | catalogued as rs550906648; called by muse, mutect2, varscan2
- CXCR6 | c.771C>T p.H257= | Silent (SNP) | VAF 228/429 reads (53%) | catalogued as rs1447643070; called by muse, mutect2, varscan2
- DBF4B | c.540G>A p.R180= | Silent (SNP) | VAF 47/324 reads (15%) | called by muse, mutect2, varscan2
- DCAKD | c.249C>G p.L83= | Silent (SNP) | VAF 125/479 reads (26%) | called by muse, mutect2, varscan2
- DCHS1 | c.5958G>A p.L1986= | Silent (SNP) | VAF 218/605 reads (36%) | catalogued as COSV55031013; called by muse, mutect2, varscan2
- DNAH17 | c.66C>T p.F22= | Silent (SNP) | VAF 112/313 reads (36%) | called by muse, mutect2, varscan2
- ELMO2 | c.2148C>T p.V716= | Silent (SNP) | VAF 47/232 reads (20%) | called by muse, mutect2
- EYS | c.7548G>A p.L2516= | Silent (SNP) | VAF 91/330 reads (28%) | called by muse, mutect2, varscan2
- FAM189A1 | c.531C>G p.L177= | Silent (SNP) | VAF 95/411 reads (23%) | called by muse, mutect2, varscan2
- FAT4 | c.10173C>T p.V3391= | Silent (SNP) | VAF 107/405 reads (26%) | catalogued as rs1301574952; called by muse, mutect2, varscan2
- FOXF1 | c.717C>T p.H239= | Silent (SNP) | VAF 160/718 reads (22%) | catalogued as COSV99296296; called by muse, mutect2, varscan2
- FSIP2 | c.4080T>C p.C1360= | Silent (SNP) | VAF 58/268 reads (22%) | called by muse, mutect2, varscan2
- GNA12 | c.420G>T p.L140= | Silent (SNP) | VAF 146/615 reads (24%) | catalogued as COSV51746493; called by muse, mutect2, varscan2
- GPR1 | c.702G>A p.K234= | Silent (SNP) | VAF 101/353 reads (29%) | called by muse, mutect2, varscan2
- HDAC9 | c.2277C>T p.I759= | Silent (SNP) | VAF 148/464 reads (32%) | catalogued as rs1060499865, COSV67775548; ClinVar: likely benign; called by muse, mutect2, varscan2
- HEATR3 | c.318C>G p.L106= | Silent (SNP) | VAF 54/276 reads (20%) | catalogued as COSV53530196; called by muse, mutect2, varscan2
- HERC1 | c.13353C>G p.V4451= | Silent (SNP) | VAF 78/387 reads (20%) | called by muse, mutect2, varscan2
- HYOU1 | c.534C>G p.V178= | Silent (SNP) | VAF 117/303 reads (39%) | catalogued as rs1345794690; called by muse, mutect2, varscan2
- INSC | c.1197C>T p.I399= | Silent (SNP) | VAF 62/485 reads (13%) | catalogued as rs1564914013, COSV65410413; called by muse, mutect2, varscan2
- KIFC3 | c.879G>C p.L293= | Silent (SNP) | VAF 181/530 reads (34%) | called by muse, mutect2, varscan2
- KLHL34 | c.1122G>A p.E374= | Silent (SNP) | VAF 19/408 reads (5%) | called by muse, mutect2
- KRT81 | c.1422G>A p.L474= | Silent (SNP) | VAF 138/479 reads (29%) | catalogued as rs748777793; called by muse, mutect2, varscan2
- LAMA4 | c.2970C>T p.N990= (on ENST00000230538 / NM_001105206.3; = p.N983= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 91/295 reads (31%) | called by muse, mutect2, varscan2
- MANEA | c.841C>T p.L281= | Silent (SNP) | VAF 117/375 reads (31%) | catalogued as COSV62590011; called by muse, mutect2, varscan2
- MTHFD1L | c.219C>G p.S73= | Silent (SNP) | VAF 28/598 reads (5%) | called by muse, mutect2
- MUC12 | c.8181G>A p.S2727= (on ENST00000379442; = p.S2584= on NM_001164462.1) | Silent (SNP) | VAF 99/931 reads (11%) | called by muse, mutect2, varscan2
- NOMO1 | c.2319C>G p.L773= | Silent (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- NTAQ1 | c.207G>A p.A69= | Silent (SNP) | VAF 83/447 reads (19%) | catalogued as rs374491156; called by muse, mutect2, varscan2
- OR10J4 | c.522C>A p.L174= | Silent (SNP) | VAF 51/283 reads (18%) | called by mutect2, varscan2
- OR9G1 | c.720C>T p.C240= | Silent (SNP) | VAF 123/949 reads (13%) | catalogued as rs896979856; called by muse, mutect2, varscan2
- OTOP3 | c.213C>T p.L71= | Silent (SNP) | VAF 82/1722 reads (5%) | called by muse, mutect2
- PDE8B | c.2571G>A p.L857= | Silent (SNP) | VAF 118/373 reads (32%) | called by muse, mutect2, varscan2
- PHC1 | c.168C>T p.F56= | Silent (SNP) | VAF 100/406 reads (25%) | called by muse, mutect2, varscan2
- PLEC | c.12177C>G p.T4059= (on ENST00000322810 / NM_201380.4; = p.T3949= on NM_000445.5) | Silent (SNP) | VAF 106/487 reads (22%) | called by muse, mutect2, varscan2
- PLEC | c.11496C>G p.V3832= (on ENST00000322810 / NM_201380.4; = p.V3722= on NM_000445.5) | Silent (SNP) | VAF 157/775 reads (20%) | called by muse, mutect2, varscan2
- PLPPR5 | c.144C>T p.S48= | Silent (SNP) | VAF 167/589 reads (28%) | called by muse, mutect2, varscan2
- PLXNB2 | c.5094C>T p.F1698= | Silent (SNP) | VAF 158/552 reads (29%) | catalogued as rs755761136; called by muse, mutect2, varscan2
- POLA1 | c.1626C>T p.F542= | Silent (SNP) | VAF 135/227 reads (59%) | catalogued as COSV66891001; called by muse, mutect2, varscan2
- RNF215 | c.1056G>T p.V352= | Silent (SNP) | VAF 40/480 reads (8%) | called by muse, mutect2
- RPL37 | c.187C>A p.R63= | Silent (SNP) | VAF 104/544 reads (19%) | catalogued as COSV57038084; called by muse, mutect2, varscan2
- SETX | c.1575C>G p.S525= | Silent (SNP) | VAF 17/531 reads (3%) | catalogued as COSV99810362; called by muse, mutect2
- SMAP1 | c.1383C>T p.L461= (on ENST00000370455 / NM_001044305.3; = p.L434= on NM_021940.5) | Silent (SNP) | VAF 63/263 reads (24%) | catalogued as COSV100017377; called by muse, mutect2, varscan2
- SOX30 | c.1897C>A p.R633= (on ENST00000265007 / NM_178424.2; = p.V468= on NM_007017.2) | Silent (SNP) | VAF 53/324 reads (16%) | called by muse, mutect2, varscan2
- SPATA31D3 | c.2388T>G p.S796= | Silent (SNP) | VAF 188/346 reads (54%) | called by muse, mutect2, varscan2
- STIM2 | c.2226G>A p.K742= | Silent (SNP) | VAF 62/215 reads (29%) | called by muse, mutect2, varscan2
- SYNE2 | c.18894C>T p.N6298= | Silent (SNP) | VAF 37/450 reads (8%) | catalogued as COSV59939846; called by muse, mutect2
- TACC2 | c.2715C>T p.L905= | Silent (SNP) | VAF 143/560 reads (26%) | called by muse, mutect2, varscan2
- TAF4 | c.210C>T p.A70= | Silent (SNP) | VAF 106/273 reads (39%) | called by muse, varscan2
- TICRR | c.2901C>G p.A967= | Silent (SNP) | VAF 58/217 reads (27%) | catalogued as COSV51541799; called by muse, mutect2, varscan2
- TM7SF3 | c.297C>T p.F99= | Silent (SNP) | VAF 99/400 reads (25%) | called by muse, mutect2, varscan2
- TMOD2 | c.687G>A p.K229= | Silent (SNP) | VAF 93/267 reads (35%) | called by muse, mutect2, varscan2
- TRIM49 | c.1329C>G p.L443= | Silent (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- TTC6 | c.150C>T p.I50= (on ENST00000267368; = p.I1319= on NM_001310135.3) | Silent (SNP) | VAF 78/413 reads (19%) | called by muse, mutect2, varscan2
- UBR3 | c.15C>T p.A5= | Silent (SNP) | VAF 167/484 reads (35%) | catalogued as rs1033817353; called by muse, mutect2, varscan2
- UNC80 | c.4887G>A p.L1629= | Silent (SNP) | VAF 94/424 reads (22%) | called by muse, mutect2, varscan2
- ZNF282 | c.1563C>T p.P521= | Silent (SNP) | VAF 175/681 reads (26%) | catalogued as rs141536445, COSV100021389; called by muse, mutect2, varscan2
- ZNF670 | c.888C>T p.L296= | Silent (SNP) | VAF 59/372 reads (16%) | called by muse, mutect2, varscan2
- ARL6IP5 | c.*255G>C | 3'UTR (SNP) | VAF 64/326 reads (20%) | called by muse, mutect2, varscan2
- DOK7 | chr4:3496833 C>T | 3'Flank (SNP) | VAF 95/421 reads (23%) | catalogued as rs760282991; called by muse, mutect2, varscan2
- H2BP2 | chr1:143876197 G>A | 3'Flank (SNP) | VAF 83/878 reads (9%) | catalogued as rs1479938466; called by muse, mutect2, varscan2
- PITX2 | c.185-950G>C | Intron (SNP) | VAF 141/519 reads (27%) | called by muse, mutect2, varscan2
- PSMD6 | c.146-132C>T | Intron (SNP) | VAF 96/384 reads (25%) | catalogued as rs1188762387; called by muse, mutect2, varscan2
- RABL6 | c.-1G>A | 5'UTR (SNP) | VAF 177/544 reads (33%) | called by muse, mutect2, varscan2
- RBBP7 | c.17-346C>G | Intron (SNP) | VAF 180/308 reads (58%) | called by muse, varscan2
- SENP3 | c.716-131G>C | Intron (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2
- SLC39A14 | c.457+1541C>T | Intron (SNP) | VAF 141/578 reads (24%) | catalogued as COSV51485585; called by muse, mutect2, varscan2
- SPTLC1 | c.*147G>A | 3'UTR (SNP) | VAF 99/365 reads (27%) | catalogued as rs544879549; called by muse, mutect2, varscan2
- TMEM116 | c.-94C>G | 5'UTR (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.10360+1775G>C | Intron (SNP) | VAF 60/301 reads (20%) | catalogued as rs1458319550, COSV59950440, COSV60212092; called by muse, mutect2, varscan2
